Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A1I5, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A1I5-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

105-0-3

Melanoma, NOS 8720/3

Site: Skin, NOS C44.9 3/12/11 per

Clinical History and Impression:

Metastatic melanoma left ulna, year old female with history of melanoma of the face.

Specimen(s) Received:

- 1: PROXIMAL MARGIN LEFT ULNA- FROZEN
- 2: LEFT ULNA
- 3: RE- EXCISION PRONATOR- FROZEN
- 4: LEFT RADIAL MARGIN

FINAL DIAGNOSIS

1) BONE, LEFT ULNA, PROXIMAL MARGIN, EXCISION:

- PERMANENT SECTIONS CONFIRM FROZEN SECTION DIAGNOSIS
- NEGATIVE FOR MALIGNANCY

2) LEFT ULNA, EXCISION:

- METASTATIC MELANOMA
- MARGINS NEGATIVE

3) PRONATOR MUSCLE, EXCISION:

- PERMANENT SECTIONS CONFIRM FROZEN SECTION DIAGNOSIS
- NEGATIVE FOR MALIGNANCY

4) BONE, LEFT RADIAL MARGIN, EXCISION:

- BONE, WITHOUT SIGNIFICANT ABNORMALITY
- NEGATIVE FOR MALIGNANCY

Pathologist:

M.D.

- Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

based the diagnosis on that evaluation.

Gross Description: ([redacted] M.D., Ph.D.; [redacted] M.D.)

1) Received fresh, labelled with the patient's name, unit number and "proximal margin left ulna, ?tumor" is a pink-tan bony tissue measuring 1 x 0.8 x 0.3 cm. Entirely submitted for frozen section. The remainder of the frozen section material is now entirely submitted in cassette #1 labelled FS for frozen section following decalcification.

2) Received fresh, labelled with the patient's name, unit number and "left ulna-long distal, short ulna" is a 7.2 x 3.4 x 2.5 resection of bone and adjacent soft tissue with an overlying skin ellipse measuring 2.9 x 0.5 cm. The portion of the specimen marked by short ulna is inked black and the other side is inked blue. The specimen is sectioned to reveal a 3.5 x 2.2 x 2.2 cm heterogenous white nodule which involves and obliterates portions of the ulna and abuts the resection margins. Representative sections are submitted in five cassettes with the proximal margin in cassette #1 and distal margin in cassette #5 following decalcification.

3) Received fresh, labelled with the patient's name, unit number and "soft tissue re-excision pronator" is a 2 x 1.5 x 0.5 cm muscle, entirely submitted for frozen section diagnosis. The remainder of the frozen section material is now entirely submitted in one cassette labelled FS.

4) Received fresh, labelled with the patient's name, unit number and "left radial margin" is a 2.3 x 0.7 x 0.2 cm fragment of bone with scant amount of attached soft tissue which reveals no gross abnormalities. The specimen is inked black, serially sectioned, and entirely submitted in one cassette following decalcification.

Frozen/Intraoperative Diagnosis: ([redacted] M.D.; [redacted] M.D.)

1) "Left ulna proximal margin, excision: Bone and soft tissue negative for melanoma (1 block) (As [redacted])."

3) "Soft tissue, re-excision pronator: Skeletal muscle, negative for melanoma. Note: Incision in ulnar aspect of the main specimen is iatrogenic, do not ink surface as margin, grossly case reviewed with Dr. [redacted] - most suspicious area on the left ulna, resection is adjacent to re-excision. The excision evaluated at frozen (1 block) (As per Drs. [redacted])."

Summary of Tissue Submitted for Microscopic Examination

	# Blocks	Block Detail	
		Designation	Description
Part 1) PROXIMAL MARGIN LEFT ULNA- FROZEN	1	FS	(1) Frozen Section
Part 2) LEFT ULNA	5	DM	(1) Distal Margin
		PM	(1) Proximal Margin
		T	(3) Tumor
Part 3) RE- EXCISION PRONATOR-FROZEN	1	FS	(1) Frozen Section
Part 4) LEFT RADIAL MARGIN	1	RM	(1) Radial Margin
Total:	8		

END OF REPORT

Source: NCI Genomic Data Commons file bd72dbaf-ea69-4db7-a6ce-2fae92a293c8 (TCGA-DA-A1I5.C10C801B-11B3-4F10-92B3-306806FBC6EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).